TCGA case TCGA-12-3648 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/407849a8-8447-4ede-a9d1-c1dfb535222e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 819 days (2.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 61.5 years (22,463 days); Year of diagnosis: 2007; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 67 days; Treatment dose: 6,000 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 14 days; Days to treatment end: 67 days; Number of cycles: 1; Treatment dose: 5,880 mg; Prescribed dose: 75; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: PEP-3-KLH Conjugate Vaccine; Treatment intent type: Adjuvant; Days to treatment start: 83 days; Days to treatment end: 452 days (1.2 years); Treatment dose: 6,500 ug; Prescribed dose: 500; Prescribed dose units: ug; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 126 days; Days to treatment end: 452 days (1.2 years); Number of cycles: 11; Treatment dose: 46,200 mg; Prescribed dose: 100; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 508 days (1.4 years); Days to treatment end: 731 days (2.0 years); Treatment dose: 10,950 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 508 days (1.4 years); Days to treatment end: 731 days (2.0 years); Number of cycles: 5; Treatment dose: 3,450 mg; Prescribed dose: 125; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 738 days (2.0 years); Days to treatment end: 784 days (2.1 years); Treatment dose: 1,400 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Recurrent Disease; Days to treatment start: 738 days (2.0 years); Days to treatment end: 784 days (2.1 years); Number of cycles: 1; Treatment dose: 1,575 mg; Prescribed dose: 50; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Recurrent Disease; Days to treatment start: 738 days (2.0 years); Days to treatment end: 784 days (2.1 years); Number of cycles: 1; Treatment dose: 2,800 mg; Prescribed dose: 50; Prescribed dose units: mg; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 61.7 years (22,549 days); Days to diagnosis: 86 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 467 days (1.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (5 entries)
- Day 86 (post initial treatment): Progression or recurrence: Yes; Days to progression: 86 days.
- Days to follow up: 784 days (2.1 years); Disease response: With Tumor.
- Days to follow up: 819 days (2.2 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-3648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-12-3648-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 40; Percent stromal cells: 10.
  Slide TCGA-12-3648-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0.
- Sample TCGA-12-3648-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-3648-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Pharmaceutical therapy drug name: CPT 11; Therapy regimen: Recurrence.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Vp 16; Therapy regimen: Recurrence.
- Drug treatment 5: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Recurrence.
- Drug treatment 8: Pharmaceutical therapy drug name: PEP3 KLH.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 819 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 819 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 86 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-3648-01A-01D-0911-01): tumor purity 0.93, ploidy 2.04, whole-genome doublings 0.
